TARGET case TARGET-10-PARELH — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a2101078-3d9f-5afa-bc6c-54f94770603f

Demographics
Sex at birth: male; Age at index: 11 years; Vital status: Dead; Days to death: 486 days (1.3 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 11.9 years (4,348 days); Year of diagnosis: 2007; Days to last follow up: 486 days (1.3 years).
   Treatment given: Protocol identifier: AALL0232.

Follow-up (2 entries)
- Days to follow up: 48 days; Days to first event: 48 days; First event: Induction Failure.
- Days to follow up: 486 days (1.3 years); Year of follow up: 2008.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Positive.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 57.6 ×10³/µL.
- Day 8: Bone Marrow blast count 83%; Minimal Residual Disease (Flow Cytometry) 49.6%.
- Day 15: Bone Marrow blast count 51%.
- Day 29: Bone Marrow blast count 35%; Minimal Residual Disease (Flow Cytometry) 13.5%.

Biospecimens (2 samples)
- Sample TARGET-10-PARELH-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
- Sample TARGET-10-PARELH-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Discovery_20230727.xlsx:
- Overall Survival Time in Days: 486
- WBC at Diagnosis: 57.6
- CNS Status at Diagnosis: CNS 1
- Testicular Involvement: No
- MRD Day 8: 49.6
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 13.5
- MRD Day 29 Sensitivity: 0.01
- Bone Marrow Site of Relapse: No
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Positive
- BMA Blasts Day 8: 83
- BMA Blasts Day 15: 51
- BMA Blasts Day 29: 35
- Karyotype: 45,XY,-7,t(9;22)(q34;q11.2)[18]/46,XY[2]
- Down Syndrome: No
- DNA Index: 1
- Alternate Therapy: Chemotherapy; Radiation NOS
- Cell of Origin: B-Precursor
- ALL Molecular Subtype: BCR-ABL1
